Somatic mutation profile of tumor specimen TCGA-CV-5973-01A (aliquot TCGA-CV-5973-01A-11D-1683-08) from TCGA case TCGA-CV-5973, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tongue, NOS; AJCC pathologic stage: Stage III; Tumor grade: G3; Age at diagnosis: 62.3 years (22,771 days).
Specimen TCGA-CV-5973-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8bf619f4-53e7-4627-8382-b790e5e3c25a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CV-5973-11A (Solid Tissue Normal), aliquot TCGA-CV-5973-11A-01D-1683-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1511947d-5cff-4a53-95cd-878a43cc9692

The open-access MAF lists 64 somatic variants for this specimen: 42 protein-altering or splice-affecting, 20 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 33, Silent 20, Frame Shift Del 5, Nonsense Mutation 4, RNA 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NOTCH1 | c.5950C>T p.R1984* | Nonsense Mutation (SNP) | VAF 17/35 reads (49%) | catalogued as rs1554826746, COSV53039810; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.844C>T p.R282W | Missense Mutation (SNP) | VAF 30/34 reads (88%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934574, CM056413, CM920678, COSV52662048, COSV52662222, COSV52701296; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ASPM | c.1693T>A p.S565T | Missense Mutation (SNP) | VAF 27/112 reads (24%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as COSV54138454; called by muse, mutect2, varscan2
- AXDND1 | c.2633A>T p.K878M | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.157); catalogued as COSV62642246; called by muse, mutect2, varscan2
- BMS1 | c.2963C>T p.P988L | Missense Mutation (SNP) | VAF 32/57 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1427832263, COSV100996392; called by muse, mutect2, varscan2
- C2CD2 | c.1265C>T p.A422V | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as COSV61600316, COSV61600482; called by muse, mutect2, varscan2
- CACNA1D | c.5830C>T p.P1944S (on ENST00000350061 / NM_001128840.3; = p.P1964S on NM_000720.4) | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT tolerated, low confidence (0.69); PolyPhen benign (0.007); catalogued as COSV55445821; called by muse, mutect2, varscan2
- CDC42BPB | c.639_640insTGA p.H213_I214ins* | Nonsense Mutation (INS) | VAF 75/137 reads (55%) | catalogued as COSV100775041, COSV63476761; called by mutect2, pindel, varscan2
- CENPBD1 | c.107C>T p.A36V | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as rs1291057353, COSV51918732; called by muse, mutect2, varscan2
- CLDN22 | c.163_164del p.V55Hfs*13 | Frame Shift Del (DEL) | VAF 22/96 reads (23%) | catalogued as rs1247724278; called by pindel, varscan2
- CLUH | c.2359C>T p.R787C (on ENST00000435359; = p.R826C on NM_015229.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs925101230, COSV70930069; called by muse, mutect2, varscan2
- CPM | c.451G>A p.D151N | Missense Mutation (SNP) | VAF 27/54 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV58035958; called by muse, mutect2, varscan2
- GNB3 | c.776A>G p.Q259R | Missense Mutation (SNP) | VAF 72/196 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.067); catalogued as COSV57530314; called by muse, mutect2, varscan2
- HEXA | c.856A>G p.T286A | Missense Mutation (SNP) | VAF 28/57 reads (49%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as COSV51506258; called by muse, mutect2, varscan2
- IRX6 | c.185C>T p.P62L | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.57); catalogued as rs759942468, COSV51862909; called by muse, mutect2
- NRXN1 | c.3934G>A p.A1312T | Missense Mutation (SNP) | VAF 16/93 reads (17%) | SIFT tolerated (0.58); PolyPhen benign (0.014); catalogued as COSV60521895; called by muse, mutect2, varscan2
- NRXN2 | c.2428G>A p.E810K | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.962); catalogued as rs773627227, COSV55452490; called by muse, mutect2
- OR2T11 | c.560C>A p.A187E | Missense Mutation (SNP) | VAF 19/95 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.021); catalogued as rs1558172034, COSV58187231; called by muse, mutect2, varscan2
- PAX1 | c.1507C>T p.R503C | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.353); catalogued as rs773700452, COSV101270162, COSV101270345; called by muse, mutect2
- PDLIM2 | c.131G>A p.R44Q (on ENST00000397760; = p.R294Q on NM_021630.6) | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT tolerated (0.33); PolyPhen benign (0.024); catalogued as rs772195717, COSV99747036; called by muse, mutect2, varscan2
- PLA2G4C | c.997G>A p.E333K | Missense Mutation (SNP) | VAF 43/183 reads (23%) | SIFT tolerated (0.84); PolyPhen benign (0.001); catalogued as rs376850000; called by muse, mutect2, varscan2
- PLXNB2 | c.3170C>T p.S1057F | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV63784358; called by muse, mutect2, varscan2
- POLQ | c.4081C>T p.Q1361* | Nonsense Mutation (SNP) | VAF 26/194 reads (13%) | catalogued as COSV51750955; called by muse, mutect2, varscan2
- PRSS54 | c.223G>A p.E75K | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.878); catalogued as rs142664927; called by muse, mutect2, varscan2
- RBM43 | c.170C>T p.T57I | Missense Mutation (SNP) | VAF 51/128 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV58879890; called by muse, mutect2, varscan2
- RELCH | c.2257C>A p.Q753K | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.631); catalogued as COSV56885163, COSV56886306; called by muse, mutect2, varscan2
- RNASE13 | c.146G>A p.R49Q | Missense Mutation (SNP) | VAF 84/133 reads (63%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs146892669, COSV58794513; called by muse, mutect2, varscan2
- RNF25 | c.616G>A p.V206M | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.14); catalogued as rs1302519500, COSV55309645; called by muse, mutect2, varscan2
- RTL5 | c.927A>C p.R309S | Missense Mutation (SNP) | VAF 44/125 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.672); catalogued as COSV65454944; called by muse, mutect2, varscan2
- SLC22A16 | c.379G>A p.D127N | Missense Mutation (SNP) | VAF 57/139 reads (41%) | SIFT tolerated (0.18); PolyPhen benign (0.376); catalogued as COSV57934539; called by muse, mutect2, varscan2
- SRMS | c.125C>T p.P42L | Missense Mutation (SNP) | VAF 84/396 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV53920314; called by muse, mutect2, varscan2
- STK38 | c.495C>G p.I165M | Missense Mutation (SNP) | VAF 24/85 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV57708775; called by muse, mutect2, varscan2
- TLN2 | c.4930G>A p.D1644N | Missense Mutation (SNP) | VAF 39/142 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs750169478, COSV60889329; called by muse, mutect2, varscan2
- XKR3 | c.38C>A p.T13K | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT tolerated (0.9); PolyPhen benign (0.234); catalogued as COSV58887903; called by muse, mutect2, varscan2
- ZMYND11 | c.1621G>C p.E541Q | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.934); catalogued as COSV59081916; called by muse, mutect2, varscan2
- ZNF71 | c.136G>T p.E46* | Nonsense Mutation (SNP) | VAF 8/39 reads (21%) | catalogued as COSV60150082; called by muse, mutect2, varscan2
- ZNF99 | c.356G>A p.S119N | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT tolerated (0.43); PolyPhen probably damaging (0.98); catalogued as rs1275658766, COSV68056722; called by muse, mutect2, varscan2
- ARAP1 | c.2255_2258delinsGCT p.K752Sfs*30 (on ENST00000393609 / NM_001040118.2; = p.K507Sfs*30 on NM_015242.4) | Frame Shift Del (DEL) | VAF 91/263 reads (35%) | called by pindel, varscan2*
- CDKN2A | c.69_72del p.R24* | Frame Shift Del (DEL) | VAF 7/18 reads (39%) | called by mutect2, varscan2
- HJURP | c.929del p.C310Sfs*22 | Frame Shift Del (DEL) | VAF 8/29 reads (28%) | called by mutect2, pindel*, varscan2
- HLA-B | c.926_927del p.V309Gfs*24 | Frame Shift Del (DEL) | VAF 17/51 reads (33%) | called by mutect2, pindel, varscan2
- IGKV3-20 | c.42G>T p.W14C | Missense Mutation (SNP) | VAF 28/113 reads (25%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- CD55 | c.750G>A p.T250= | Silent (SNP) | VAF 35/116 reads (30%) | catalogued as rs780475447, COSV58578000; called by muse, mutect2, varscan2
- ETV1 | c.1296A>G p.P432= | Silent (SNP) | VAF 11/30 reads (37%) | catalogued as rs944330475, COSV54151232; called by muse, mutect2, varscan2
- FJX1 | c.885C>T p.F295= | Silent (SNP) | VAF 10/60 reads (17%) | catalogued as rs77030854, COSV100502565; called by muse, mutect2, varscan2
- FOCAD | c.3516C>T p.H1172= | Silent (SNP) | VAF 12/33 reads (36%) | catalogued as rs540425752, COSV58107513; called by muse, mutect2, varscan2
- FOXB2 | c.930C>T p.V310= | Silent (SNP) | VAF 6/16 reads (38%) | catalogued as COSV100942262; called by muse, mutect2, varscan2
- HOMER3 | c.441C>T p.N147= | Silent (SNP) | VAF 31/127 reads (24%) | catalogued as COSV55355581; called by muse, mutect2, varscan2
- HSF5 | c.1713G>A p.K571= | Silent (SNP) | VAF 17/45 reads (38%) | catalogued as COSV60419513; called by muse, mutect2, varscan2
- HYDIN | c.3822A>G p.E1274= | Silent (SNP) | VAF 24/47 reads (51%) | catalogued as COSV66834323; called by muse, mutect2, varscan2
- LRRC8A | c.2346C>T p.S782= | Silent (SNP) | VAF 7/22 reads (32%) | catalogued as rs777181644, COSV52189180; ClinVar: likely benign; called by muse, mutect2, varscan2
- MAP4 | c.2730G>A p.S910= | Silent (SNP) | VAF 30/75 reads (40%) | catalogued as rs146957827; called by muse, mutect2, varscan2
- MS4A2 | c.441C>T p.I147= | Silent (SNP) | VAF 29/119 reads (24%) | catalogued as rs773315133, COSV54013839; called by muse, mutect2, varscan2
- NAV3 | c.1527C>A p.G509= | Silent (SNP) | VAF 15/57 reads (26%) | catalogued as COSV57111321; called by muse, mutect2, varscan2
- PPP2R3A | c.1914A>T p.S638= | Silent (SNP) | VAF 23/104 reads (22%) | catalogued as COSV53870553; called by muse, mutect2
- PTCH2 | c.2583C>A p.T861= | Silent (SNP) | VAF 39/247 reads (16%) | catalogued as COSV64710789, COSV64713465; called by muse, mutect2, varscan2
- PTPRN | c.1299C>T p.P433= | Silent (SNP) | VAF 34/91 reads (37%) | catalogued as COSV55350803, COSV55352183; called by muse, mutect2, varscan2
- SEC14L2 | c.300C>T p.Y100= | Silent (SNP) | VAF 45/135 reads (33%) | catalogued as rs144595900; called by muse, mutect2, varscan2
- SETDB1 | c.1815A>G p.L605= | Silent (SNP) | VAF 40/82 reads (49%) | catalogued as rs758639919, COSV54992257; called by muse, mutect2, varscan2
- SLC4A2 | c.3435G>A p.P1145= | Silent (SNP) | VAF 15/61 reads (25%) | catalogued as rs774486594, COSV52539760; called by muse, mutect2, varscan2
- TULP1 | c.300C>T p.R100= | Silent (SNP) | VAF 6/14 reads (43%) | catalogued as COSV57693857; called by muse, mutect2
- ZNF816 | c.1260T>A p.T420= | Silent (SNP) | VAF 51/92 reads (55%) | catalogued as COSV54412472; called by muse, mutect2, varscan2
- HMGB1P1 | n.376G>A | RNA (SNP) | VAF 18/65 reads (28%) | called by muse, mutect2, varscan2
- MIR1-1HG-AS1 | n.856G>A | RNA (SNP) | VAF 10/58 reads (17%) | catalogued as rs781951929; called by muse, mutect2
